Gene-level copy-number profile of tumor specimen TCGA-2E-A9G8-01A from TCGA case TCGA-2E-A9G8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage III; Tumor grade: G2.
Specimen TCGA-2E-A9G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.18f505a8-5a1e-4325-a244-b3b5e372b5c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2E-A9G8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 834 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/20ff2101-9beb-41d3-be3c-5694a2157592

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 13,314; copy number 2: 38,647; copy number 3: 6,811; copy number 4: 677; copy number 5: 147; copy number 6: 27; copy number 7: 162.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2E-A9G8-01A-11D-A402-01): tumor purity 0.93, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:22,811,390–23,134,824, 4 genes: AC114477.1, RANP7, SALL4P5, RPL24P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 336 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:171,439,526–171,534,615, 5 genes, copy number 5: Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1.
- chr3:172,560,888–172,604,006, 2 genes, copy number 5 (within-gene range 3–5): LINC02068, SLC31A1P1.
- chr7:139,025,706–139,777,998, 20 genes, copy number 6: ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2.
- chr18:3,466,250–3,478,978, 1 gene, copy number 6 (within-gene range 3–6): GAPLINC.
- chr18:3,571,215–3,771,430, 6 genes, copy number 6: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2.
- chr19:8,302,127–10,836,318, 139 genes, copy number 5 (broad region; genes not listed).
- chr19:10,841,839–10,842,250, 1 gene, copy number 5: HIKESHIP2.
- chr19:15,673,018–17,895,174, 132 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:18,418,864–18,958,258, 30 genes, copy number 7: SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1, AC005253.2, UBA52, CRLF1, REX1BD, TMEM59L, RN7SL155P, KLHL26, CRTC1, COMP, UPF1, GDF1, CERS1, AC005197.1, COPE, AC002985.1, DDX49, HOMER3, HOMER3-AS1, RN7SL70P.

Autosomal genes at a single copy (total copy number 1): 13,308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
